Somatic mutation profile of tumor specimen TARGET-10-PATYCH-09A (aliquot TARGET-10-PATYCH-09A-01D) from TARGET case TARGET-10-PATYCH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,432 days).
Specimen TARGET-10-PATYCH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 582467f0-7681-45ca-8402-87db9894d0a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATYCH-10A (Blood Derived Normal), aliquot TARGET-10-PATYCH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09601ec5-1beb-4397-834f-546a4c25149b

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 79/261 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRINP3 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66530962; called by muse, mutect2, varscan2
- CNGB1 | c.3207T>A p.Y1069* | Nonsense Mutation (SNP) | VAF 88/287 reads (31%) | catalogued as COSV51903353; called by muse, mutect2, varscan2
- NCOR1 | c.3389G>A p.G1130D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV51983941; called by muse, mutect2, varscan2
- NOTCH1 | c.7375del p.Q2459Rfs*18 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as COSV53025731; called by mutect2, varscan2
- NOTCH1 | c.4775_4776insTGGGTC p.F1592_L1593insGS | In Frame Ins (INS) | VAF 24/57 reads (42%) | catalogued as COSV53024877, COSV53028189, COSV53038773, COSV53042822, COSV53047824, COSV53049150, COSV53050117, COSV53053941, COSV53058597, COSV53059642, COSV53059832, COSV53063931, COSV53065478, COSV53068542, COSV53073834, COSV5…; called by mutect2, pindel, varscan2
- PKHD1L1 | c.4030G>T p.G1344C | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65747230; called by muse, mutect2, varscan2
- PLSCR1 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61013367; called by muse, mutect2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- SLC6A2 | c.56C>A p.T19K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54922619; called by muse, mutect2
- SPEG | c.4195G>A p.V1399M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs750885704, COSV56674011; called by mutect2, varscan2
- ARID1A | c.5418_5419insCGTCTCCCTC p.S1807Rfs*5 | Frame Shift Ins (INS) | VAF 25/117 reads (21%) | called by mutect2, pindel, varscan2
- HELZ | c.4886G>T p.S1629I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SCUBE3 | c.324C>A p.H108Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZBTB38 | c.1187C>A p.S396* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- ZBTB49 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2
- CCND1 | c.513G>A p.A171= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV99919648; called by muse, varscan2
- CSNK1A1 | c.936C>T p.S312= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- LST1 | c.*29C>A | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- TMEM191C | c.472-51C>T | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as rs3819059; called by muse, mutect2
